Gene-level copy-number profile of tumor specimen TCGA-EK-A2PM-01A from TCGA case TCGA-EK-A2PM, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 81.4 years (29,747 days).
Specimen TCGA-EK-A2PM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.ddd0d360-7ea7-4085-a392-60242b314eb0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EK-A2PM-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2749b305-4749-4a21-9faf-0c1b00667657

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 25; copy number 1: 702; copy number 2: 23,062; copy number 3: 8,863; copy number 4: 20,644; copy number 5: 3,414; copy number 6: 1,531; copy number 7: 1,213; copy number 8: 346; copy number 11: 17.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EK-A2PM-01A-11D-A18H-01): tumor purity 0.7, ploidy 3.27, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 25 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:26,859,806–26,874,349, 2 genes: STIM2-AS1, PIMREGP4.
- chr10:34,201,979–34,202,074, 1 gene: Y_RNA.
- chr14:49,927,571–50,105,043, 1 gene (within-gene range 0–2): LINC01588.
- chr14:50,050,368–50,335,558, 10 genes: PDLIM1P1, AL117692.1, RN7SKP193, Y_RNA, VCPKMT, SOS2, L2HGDH, MIR4504, DMAC2L, AL359397.2.
- chr16:9,365,540–9,614,899, 5 genes (within-gene range 0–2): AC012178.1, LINC01177, LINC01195, AC007221.1, RNA5SP403.
- chr16:11,547,722–11,679,152, 2 genes: LITAF, SNN.
- chr18:47,808,957–47,931,146, 4 genes (within-gene range 0–2): SMAD2, MTCO2P2, AC120349.3, AC120349.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6,521 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:60,515,716–73,915,340, 198 genes, copy number 5 (broad region; genes not listed).
- chr1:172,366,540–248,919,946, 1,533 genes, copy number 6–11 (broad region; genes not listed).
- chr2:104,794,848–105,962,386, 22 genes, copy number 5: PANTR1, AC018730.1, POU3F3, LINC01159, AC010884.1, MRPS9-AS2, MRPS9, MRPS9-AS1, LINC01918, GPR45, AC012360.2, TGFBRAP1, AC012360.1, AC012360.3, C2orf49, FHL2, AC108058.1, AC018802.1, AC018802.2, NCK2, AC010978.1, AC009505.1.
- chr3:11,745–15,722,311, 249 genes, copy number 5–7 (broad region; genes not listed).
- chr3:15,697,298–15,738,809, 4 genes, copy number 5: MIR3134, AC090950.2, AC090950.1, RN7SL4P.
- chr3:140,902,194–148,591,927, 106 genes, copy number 6 (broad region; genes not listed).
- chr3:180,707,589–180,871,005, 1 gene, copy number 6 (within-gene range 4–6): AC108734.4.
- chr3:180,772,750–198,222,513, 408 genes, copy number 5–6 (broad region; genes not listed).
- chr6:167,607–37,819,218, 1,131 genes, copy number 5 (broad region; genes not listed).
- chr6:37,832,922–37,833,185, 1 gene, copy number 5: RN7SL285P.
- chr6:38,168,451–52,284,881, 284 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr7:65,335,174–139,228,605, 1,295 genes, copy number 5–6 (broad region; genes not listed).
- chr8:69,667,046–103,141,475, 569 genes, copy number 6–8 (within-gene range 4–8) (broad region; genes not listed).
- chr8:103,371,538–140,635,633, 415 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr8:140,940,562–145,066,685, 193 genes, copy number 5 (broad region; genes not listed).
- chr18:28,638,714–33,441,101, 69 genes, copy number 7 (broad region; genes not listed).
- chr20:87,250–1,473,842, 43 genes, copy number 6 (within-gene range 4–6): DEFB125, DEFB126, DEFB127, DEFB128, DEFB129, DEFB132, AL034548.1, C20orf96, ZCCHC3, AL034548.2, NRSN2-AS1, SOX12, NRSN2, TRIB3, RBCK1, TBC1D20, Y_RNA, CSNK2A1, TCF15, SRXN1, AL121758.1, SCRT2, SLC52A3, FAM110A, RPS10P5, ANGPT4, RSPO4, AL110114.1, PSMF1, ACTG1P3, TMEM74B, AL031665.1, C20orf202, RAD21L1, SNPH, SDCBP2, AL136531.2, AL136531.3, SDCBP2-AS1, AL136531.1, FKBP1A, MIR6869, NSFL1C.

Autosomal genes at a single copy (total copy number 1): 627. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
